Somatic mutation profile of tumor specimen TCGA-FA-A4XK-01A (aliquot TCGA-FA-A4XK-01A-11D-A31X-10) from TCGA case TCGA-FA-A4XK, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Jejunum; Age at diagnosis: 40.3 years (14,723 days).
Specimen TCGA-FA-A4XK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6091e42d-1963-4225-b674-43eb75dd0fb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A4XK-10A (Blood Derived Normal), aliquot TCGA-FA-A4XK-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7368f038-0028-47b0-a4bf-c967e1a2add4

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 23, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Frame Shift Del 1, RNA 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs1553217626, CM980835, COSV100516416; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99566322; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100416687; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1037G>C p.S346T | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV100416691; called by muse, mutect2, varscan2
- ADGRB3 | c.3161T>C p.L1054P | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as COSV53241375, COSV99486200; called by muse, mutect2, varscan2
- AMPD2 | c.1318T>A p.Y440N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99857954; called by muse, mutect2, varscan2
- B3GLCT | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs144117014; called by muse, mutect2, varscan2
- BCL11B | c.710T>C p.L237P (on ENST00000357195 / NM_001282237.2; = p.L166P on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595714; called by muse, mutect2, varscan2
- BTG2 | c.113T>G p.F38C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99305866; called by muse, varscan2
- CACNA1G | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs573756072, COSV61729725; called by muse, mutect2, varscan2
- CACNA2D1 | c.2170A>G p.K724E (on ENST00000356253 / NM_001366867.1; = p.K712E on NM_000722.4) | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV100666961; called by muse, mutect2, varscan2
- CD79A | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99702057; called by muse, mutect2, varscan2
- CDK11B | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765357030, COSV100478000; called by muse, mutect2, varscan2
- CES5A | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV99307807; called by muse, mutect2
- CSNK2B | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs1246917499, COSV101021760; called by muse, mutect2, varscan2
- CTTNBP2 | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs138985857; called by muse, mutect2, varscan2
- CUL7 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs372754676; called by muse, mutect2, varscan2
- DIO2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355265132, COSV70445244; called by muse, mutect2, varscan2
- DMBT1 | c.2417A>G p.E806G | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100353620; called by muse, mutect2, varscan2
- DSCAM | c.5564C>T p.T1855M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200410460; called by muse, mutect2, varscan2
- EPHA5 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56682832; called by muse, mutect2, varscan2
- FAT4 | c.4487T>G p.V1496G | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101272532; called by muse, varscan2
- GPHN | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100016991; called by muse, mutect2, varscan2
- GPR156 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV100251585, COSV59939542; called by muse, mutect2, varscan2
- H2AC8 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55126441, COSV99773303; called by muse, mutect2, varscan2
- IFT22 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100190116; called by muse, mutect2, varscan2
- IGHV3-30 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs780759000; called by muse, varscan2
- IGHV3-30 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as rs779213628; called by muse, varscan2
- IGHV3-33 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); catalogued as rs774328930; called by muse, varscan2
- IGLV4-69 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs544457524; called by muse, varscan2
- INTS1 | c.5810C>T p.S1937F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV101248166, COSV67176405; called by muse, mutect2, varscan2
- INTS3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs769418464, COSV100016325; called by muse, mutect2, varscan2
- KCNH1 | c.480C>A p.S160R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55069632, COSV55090729; called by muse, mutect2, varscan2
- ME3 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs763016370, COSV100042010; called by muse, mutect2, varscan2
- MUC16 | c.34360C>T p.P11454S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.093); catalogued as COSV101200539; called by muse, mutect2, varscan2
- OPLAH | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs529467010, COSV101470800, COSV70678420; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR4D5 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100190101; called by muse, mutect2, varscan2
- PFN1 | c.132+1G>A p.X44_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52591448; called by muse, mutect2, varscan2
- PLEK | c.29A>T p.Y10F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99311116; called by muse, mutect2, varscan2
- PLPPR1 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.037); catalogued as COSV100883421; called by muse, mutect2, varscan2
- PLRG1 | c.1491A>T p.E497D | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.933); catalogued as COSV100123191; called by muse, mutect2, varscan2
- POGLUT3 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV100052732; called by muse, mutect2, varscan2
- PRDM1 | c.320T>A p.I107K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100958904; called by muse, mutect2, varscan2
- RB1CC1 | c.4030G>T p.E1344* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as COSV99212497; called by muse, mutect2, varscan2
- RECQL5 | c.1149+1G>A p.X383_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100512154; called by muse, mutect2, varscan2
- REV3L | c.7724A>G p.N2575S | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100725455; called by muse, mutect2, varscan2
- RPAP1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100427239; called by muse, mutect2, varscan2
- SEMA3C | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs143347984; called by muse, mutect2, varscan2
- SLC22A23 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100978328; called by muse, mutect2, varscan2
- SLC26A4 | c.779T>G p.I260S | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1218447786, COSV99707288; called by muse, mutect2, varscan2
- SMAD5 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV101548134; called by muse, mutect2, varscan2
- SMYD1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773786522, COSV101352477; called by muse, mutect2, varscan2
- SOX17 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs868625307, COSV52025416; called by muse, mutect2, varscan2
- SPATA18 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54645458, COSV99730913; called by muse, mutect2, varscan2
- TLR2 | c.980A>T p.D327V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV52605462; called by muse, mutect2, varscan2
- TNN | c.3884G>T p.R1295M | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53432533; called by muse, mutect2, varscan2
- TPO | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs371917329, COSV100219602; called by muse, mutect2, varscan2
- VCAN | c.5494T>C p.F1832L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV99426654; called by muse, mutect2, varscan2
- VPS13D | c.8093C>T p.A2698V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs143572864; called by muse, mutect2, varscan2
- VWCE | c.1233C>T p.D411= | Splice Region (SNP) | VAF 32/62 reads (52%) | catalogued as rs375996793; called by muse, mutect2, varscan2
- ZNF782 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV100001510; called by muse, mutect2, varscan2
- DLG5 | c.5067dup p.R1690Sfs*26 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by mutect2, varscan2
- IGLC2 | c.184_195del p.S62_Y66delinsN | In Frame Del (DEL) | VAF 42/260 reads (16%) | called by pindel, varscan2
- IGLC3 | c.184_195del p.S62_Y66delinsN | In Frame Del (DEL) | VAF 59/349 reads (17%) | called by pindel, varscan2
- PARP9 | c.2429_2440delinsTATTT p.G810Vfs*25 | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | called by pindel, varscan2*
- ZNF503 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC6 | c.4014G>A p.L1338= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99229231; called by muse, mutect2, varscan2
- ADAMTS3 | c.762C>T p.N254= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs779220676, COSV54389339; called by muse, mutect2, varscan2
- B3GNT8 | c.264C>T p.S88= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99524689; called by muse, mutect2, varscan2
- C10orf90 | c.336G>A p.P112= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs764315520, COSV99504635; called by muse, mutect2, varscan2
- CHRNA3 | c.537C>T p.S179= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV100468456; called by muse, mutect2, varscan2
- CPXM2 | c.783G>A p.E261= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV53870512, COSV99580921; called by muse, mutect2, varscan2
- FAAH2 | c.288G>A p.A96= | Silent (SNP) | VAF 47/54 reads (87%) | catalogued as rs56161888, COSV100887389, COSV66507598; called by muse, mutect2, varscan2
- HOXD11 | c.21C>T p.C7= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs760406908, COSV99983325; called by muse, mutect2, varscan2
- IGHG2 | c.177C>G p.S59= | Silent (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- IGLC2 | c.270G>A p.T90= | Silent (SNP) | VAF 114/365 reads (31%) | catalogued as rs774342214; called by muse, varscan2
- KIF9 | c.2178C>A p.I726= (on ENST00000265529 / NM_001377474.1; = p.I661= on NM_022342.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99646866; called by muse, mutect2, varscan2
- KRT13 | c.444T>C p.P148= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1567714576, COSV99877437; called by muse, mutect2, varscan2
- LGMN | c.1222C>T p.L408= | Silent (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- MEP1A | c.228G>T p.T76= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV100042938; called by muse, mutect2, varscan2
- MFSD6 | c.162A>C p.I54= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV99855291; called by muse, mutect2, varscan2
- MGAM | c.3588G>A p.T1196= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs181422456, COSV101527356; called by muse, mutect2, varscan2
- MYC | c.336C>T p.N112= (on ENST00000377970; = p.N127= on NM_002467.6) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV52368068, COSV52371210, COSV52373533; called by muse, mutect2, varscan2
- NWD1 | c.1407C>T p.C469= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100343227; called by muse, mutect2, varscan2
- OR4C16 | c.123G>A p.L41= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV58944783; called by muse, mutect2, varscan2
- SARDH | c.1263G>A p.G421= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1299894328, COSV100898881; called by muse, mutect2, varscan2
- SOCS3 | c.342G>T p.V114= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs942160472, COSV100434517; called by muse, mutect2, varscan2
- ZCWPW2 | c.381T>G p.T127= | Silent (SNP) | VAF 117/339 reads (35%) | catalogued as rs750962823, COSV101075066; called by muse, mutect2, varscan2
- ZFHX4 | c.3222T>C p.T1074= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs769755851, COSV99265428; called by muse, mutect2
- LINC02145 | n.392A>C | RNA (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- PGC | c.*34C>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100026348; called by muse, mutect2
